Gene-level copy-number profile of tumor specimen C3N-03433-02 from CPTAC case C3N-03433, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 76.7 years (28,032 days).
Specimen C3N-03433-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 096aafdd-1342-495e-94f1-ceeaaaf2b622.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03433-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/9b0449b9-cca3-4a24-bd8f-98839c1fc811

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 3,063; copy number 2: 21,865; copy number 3: 14,896; copy number 4: 12,103; copy number 5: 4,060; copy number 6: 1,260; copy number 7: 828; copy number 8: 186; copy number 9: 1; copy number 11: 16; copy number 12: 9; copy number 13: 20; copy number 15: 7; copy number 16: 18; copy number 27: 29.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr4:145,335,263–145,377,957, 3 genes: LINC02266, RTN3P1, AC079228.1.
- chr7:56,991,888–57,020,273, 2 genes: TNRC18P3, SLC29A4P1.
- chr15:84,199,311–84,256,014, 4 genes: GOLGA2P7, RN7SL331P, GOLGA6L4, UBE2Q2P8.
- chr19:27,757,184–28,125,430, 12 genes (within-gene range 0–2): AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1.
- chr19:28,790,812–28,970,874, 6 genes (within-gene range 0–2): MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,429 genes in 52 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,534,449–66,751,139, 698 genes, copy number 5 (broad region; genes not listed).
- chr1:143,498,785–143,739,506, 10 genes, copy number 5–8: AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2.
- chr1:143,811,359–144,068,350, 9 genes, copy number 5–6: AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D.
- chr1:150,255,095–189,037,564, 1,092 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:201,622,885–203,904,013, 86 genes, copy number 5 (broad region; genes not listed).
- chr1:223,947,605–224,228,043, 13 genes, copy number 5 (within-gene range 4–5): CICP5, GTF2IP20, RNU6-1319P, AC138393.1, AC138393.3, AC138393.2, RN7SKP49, FBXO28, AC092809.3, DEGS1, SNORA72, AC092809.2, AC092809.4.
- chr2:35,471,405–46,941,855, 191 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:69,319,780–76,595,678, 189 genes, copy number 6–9 (broad region; genes not listed).
- chr2:103,494,241–127,931,440, 397 genes, copy number 5 (broad region; genes not listed).
- chr2:173,705,948–197,676,045, 339 genes, copy number 6–7 (broad region; genes not listed).
- chr3:55,166,910–61,251,459, 73 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:93,843,764–94,507,620, 11 genes, copy number 5: RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1.
- chr3:119,579,212–123,449,090, 87 genes, copy number 5 (broad region; genes not listed).
- chr6:48,701,491–51,464,765, 36 genes, copy number 5: FO393412.1, AL022099.1, AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL360175.1, AL135908.1, TFAP2D, TFAP2B, RPS17P5, AL049693.1, FTH1P5, AL158050.2, AL158050.1, AL365219.1.
- chr6:62,460,940–72,403,143, 88 genes, copy number 5–6 (broad region; genes not listed).
- chr6:105,273,218–105,667,998, 6 genes, copy number 5: PREP, AL133406.2, AL133406.1, RPL35P3, LINC02836, Z97206.1.
- chr6:139,435,636–142,446,266, 24 genes, copy number 5: LINC01625, ATP5PBP6, AL390205.1, FILNC1, AL050338.1, AL357146.1, RNA5SP220, MIR3668, AL035446.2, MIR4465, RPS3AP24, AL035446.1, AL357084.1, AL357080.1, AL355596.1, RN7SKP106, RPS3AP23, NMBR, AL589674.1, NMBR-AS1, GJE1, VTA1, AL360007.1, ADGRG6.
- chr6:168,820,423–170,738,536, 44 genes, copy number 5: AL513210.2, AL513210.1, AL109924.3, AL109924.1, AL109924.2, LINC01615, LINC02544, BX322234.1, THBS2, BX322234.2, VTA1P1, LINC02519, AL031315.1, AL135910.1, WDR27, C6orf120, PHF10, AL354892.2, AL354892.1, TCTE3, ERMARD, AL354892.3, LINC00242, LINC00574, AL049612.1, AL596442.1, AL596442.2, RPL12P23, AL109910.1, AL109910.2, LINC01624, DLL1, FAM120B, AL078605.1, MIR4644, AL008628.1, PSMB1, TBP, PDCD2, AL672310.1, OR4F7P, WBP1LP8, AL731661.1, AL731684.1.
- chr7:32,456,963–33,877,180, 28 genes, copy number 5 (within-gene range 4–5): AC018641.1, SLC25A5P5, LSM5, AVL9, DPY19L1P1, ZNRF2P1, MIR550A2, MIR550B2, AC018645.3, LINC00997, AC018645.1, AC018645.2, DPY19L1P2, AC018648.1, KBTBD2, RP9P, AC083863.1, FKBP9, RNU6-388P, NT5C3A, RPS29P14, RN7SL505P, RP9, BBS9, AC074338.1, RNA5SP229, AC007312.1, AC006195.1.
- chr7:43,866,558–44,986,961, 52 genes, copy number 6: MRPS24, URGCP-MRPS24, URGCP, TUBG1P, UBE2D4, POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1, AC017116.2, POLR2J4, RASA4CP, LINC00957, DBNL, MIR6837, PGAM2, AC017116.1, POLM, MIR6838, AEBP1, MIR4649, POLD2, RNA5SP230, MYL7, GCK, YKT6, CAMK2B, AC004453.2, NUDCD3, AC004453.1, RNU6-1097P, AC004938.1, NPC1L1, DDX56, TMED4, AC011894.1, OGDH, ZMIZ2, AC013436.1, PPIA, H2AZ2, LINC01952, PURB, MIR4657, AC004854.2, AC004854.1, AC004847.1, MYO1G, SNHG15, SNORA9.
- chr7:63,011,463–111,562,517, 959 genes, copy number 5–7 (broad region; genes not listed).
- chr8:43,442,902–43,674,591, 9 genes, copy number 12: AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr8:127,072,694–128,564,679, 23 genes, copy number 11–15: CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr10:26,643,228–26,861,087, 10 genes, copy number 6: AL390961.1, FAM238B, SELENOOLP, AL390961.3, PDSS1, HSPA8P3, AL390961.2, ABI1, AL139404.1, RNU6-946P.
- chr10:127,549,309–133,629,507, 95 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:66,070,272–71,423,423, 197 genes, copy number 8–27 (broad region; genes not listed).
- chr12:105,173,297–106,347,003, 15 genes, copy number 5: APPL2, C12orf75, AC078874.1, KCCAT198, CASC18, ST13P3, AC011595.2, NUAK1, AC011595.1, AC010182.1, CKAP4, AC079174.1, AC079174.2, RNU7-94P, TCP11L2.
- chr13:18,467,172–19,187,618, 35 genes, copy number 5: ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP, GXYLT1P1, CNN2P12, ZNF965P, CYP4F34P, SNX18P26, LINC00328-2P, ANKRD20A9P, RHOT1P3, RNU6-55P, RNU6-76P, SNX19P2, LINC00408, AL355516.1, PHF2P2, LINC00442, USP24P1, GTF2IP3, AL137001.1, AL137001.2, RNA5SP24, CENPIP1, AL139327.2, SMPD4P2, AL139327.3, TUBA3C, AL139327.1.
- chr13:49,095,391–61,927,272, 164 genes, copy number 5–6 (broad region; genes not listed).
- chr13:100,338,982–100,675,093, 8 genes, copy number 5: AL353697.1, PCCA-AS1, GGACT, AL356966.1, AL136526.1, RPS26P47, TMTC4, COX5BP6.
- chr13:101,967,642–104,815,069, 28 genes, copy number 5: MIR2681, LIPT1P1, RNY1P2, MIR4705, RPL39P29, FGF14-IT1, AL356266.1, FGF14-AS1, FGF14-AS2, LINC00555, AL158063.1, TPP2, METTL21C, CCDC168, LINC00283, AL157769.1, TEX30, POGLUT2, BIVM-ERCC5, BIVM, ERCC5, METTL21EP, AL137246.1, AL137246.2, SLC10A2, LINC01309, ATP6V1G1P7, RPL7P45.
- chr13:111,588,201–114,337,626, 68 genes, copy number 5 (broad region; genes not listed).
- chr14:27,258,717–30,191,898, 29 genes, copy number 5 (within-gene range 4–5): AL390334.1, LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1, LINC02326, Y_RNA, AL135878.1, RNU6-864P, AL133166.1, AL158058.1, AL158058.2, RNU11-5P, PRKD1, AL356756.1, RNU6-1234P, AL355053.1.
- chr14:32,879,246–53,883,740, 319 genes, copy number 5–8 (broad region; genes not listed).
- chr14:103,331,674–103,928,269, 32 genes, copy number 5: AL138976.2, EIF5, SNORA28, HMGB3P26, RPSAP5, MARK3, RPL10AP1, CKB, AL133367.1, TRMT61A, RNU7-160P, AL139300.2, BAG5, KLC1, COA8, AL139300.1, RNU4-68P, AL049840.2, AL049840.6, AL049840.3, AL049840.4, AL049840.5, XRCC3, ZFYVE21, Y_RNA, PPP1R13B, AL049840.7, AL049840.1, LINC00637, AL132712.1, AL132712.2, ATP5MPL.
- chr17:34,360,328–39,864,312, 231 genes, copy number 5–7 (broad region; genes not listed).
- chr19:12,391,949–16,690,023, 253 genes, copy number 6–7 (within-gene range 2–7) (broad region; genes not listed).
- chr19:19,176,903–20,571,095, 76 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr19:34,837,889–38,912,158, 224 genes, copy number 6 (broad region; genes not listed).
- chr20:87,250–5,113,103, 157 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,063. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
